Somatic mutation profile of tumor specimen 2433b136-fc7b-4cea-b958-bc6efb (aliquot 2433b136-fc7b-4cea-b958-bc6efb_D6) from CPTAC case 26OV008, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 2433b136-fc7b-4cea-b958-bc6efb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c48b5c6-39db-41af-a818-ada83edbe451.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4179faf1-53d6-40ba-9d58-f111a7 (Blood Derived Normal), aliquot 4179faf1-53d6-40ba-9d58-f111a7_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/086071ea-d297-46bc-aac3-f6f41da84410

The open-access MAF lists 64 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, RNA 4, Nonsense Mutation 3, Intron 2, 5'UTR 2, Frame Shift Del 2, 3'UTR 2, In Frame Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC154 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 54/279 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs574311061; called by muse, mutect2, varscan2
- COG7 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.16); catalogued as rs752375218; called by muse, mutect2, varscan2
- EMILIN1 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs200777776; called by muse, mutect2, varscan2
- FAM184B | c.2917C>T p.R973C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188210452; called by muse, mutect2, varscan2
- FSIP2 | c.6316C>G p.L2106V | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as rs1202012772; called by muse, mutect2, varscan2
- GLIS1 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV56546791; called by muse, mutect2, varscan2
- GRAP2 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 51/97 reads (53%) | catalogued as COSV59994224; called by muse, mutect2, varscan2
- HNRNPR | c.1424A>G p.Y475C | Missense Mutation (SNP) | VAF 106/334 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs763561835; called by muse, mutect2, varscan2
- KDM4B | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV50214073; called by muse, mutect2, varscan2
- MAPK9 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV58119804; called by muse, mutect2
- PIGK | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 81/108 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as COSV104417782; called by muse, mutect2, varscan2
- PPFIA1 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV99557774; called by muse, mutect2, varscan2
- RADIL | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.321); catalogued as COSV68202175; called by muse, mutect2
- SETDB1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs781489180, COSV54976550; called by muse, mutect2, varscan2
- SIDT1 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1170287217; called by muse, mutect2, varscan2
- SUGP1 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 56/511 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs747643478, COSV55920060, COSV99895724; called by muse, mutect2, varscan2
- TP53 | c.1010del p.R337Pfs*8 | Frame Shift Del (DEL) | VAF 97/156 reads (62%) | catalogued as CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; called by mutect2, pindel, varscan2
- TTYH2 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758752057; called by muse, mutect2, varscan2
- UNKL | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 111/239 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs201836512; called by muse, mutect2, varscan2
- ABCA4 | c.5995G>A p.A1999T | Missense Mutation (SNP) | VAF 167/443 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALDH2 | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLSTN3 | c.1864T>C p.S622P | Missense Mutation (SNP) | VAF 69/1084 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- COL7A1 | c.4482G>A p.K1494= | Splice Region (SNP) | VAF 108/460 reads (23%) | called by muse, mutect2, varscan2
- DCAF5 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2
- DLX1 | c.452A>C p.Q151P | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF5B | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- GFUS | c.464_464+1insA p.A156Gfs*81 | Frame Shift Ins (INS) | VAF 30/198 reads (15%) | called by mutect2, pindel*, varscan2
- HIVEP1 | c.5497G>A p.V1833I | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IL1RN | c.460C>T p.Q154* (on ENST00000409930 / NM_173842.3; = p.Q136* on NM_000577.5) | Nonsense Mutation (SNP) | VAF 218/786 reads (28%) | called by muse, varscan2
- KCP | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KRT18 | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MTG2 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2
- MYADM | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 188/479 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAA10 | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 68/580 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OBSL1 | c.5104G>A p.V1702M | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- OCRL | c.937A>T p.K313* | Nonsense Mutation (SNP) | VAF 32/228 reads (14%) | called by muse, mutect2, varscan2
- RYR1 | c.1643G>A p.S548N | Missense Mutation (SNP) | VAF 301/733 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC34A3 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 171/717 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SP100 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TAS2R19 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 39/566 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2
- TUBA4A | c.1342_1344del p.E448del | In Frame Del (DEL) | VAF 20/84 reads (24%) | called by pindel, varscan2
- ZEB1 | c.1879_1880del p.K627Vfs*3 | Frame Shift Del (DEL) | VAF 275/724 reads (38%) | called by mutect2, pindel, varscan2
- AMOTL2 | c.1528C>T p.L510= | Silent (SNP) | VAF 145/361 reads (40%) | called by muse, mutect2, varscan2
- ANKRD10 | c.858C>T p.F286= | Silent (SNP) | VAF 63/163 reads (39%) | catalogued as rs768817174; called by muse, mutect2, varscan2
- CACNA1C | c.4323G>A p.T1441= | Silent (SNP) | VAF 41/956 reads (4%) | catalogued as rs753892795, COSV59706336; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- CCT7 | c.459G>A p.K153= | Silent (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- DTX4 | c.1305G>T p.G435= | Silent (SNP) | VAF 65/382 reads (17%) | called by muse, mutect2, varscan2
- ERBB3 | c.3237C>G p.P1079= | Silent (SNP) | VAF 20/237 reads (8%) | catalogued as COSV99917125; called by muse, mutect2
- FRS2 | c.1396A>C p.R466= | Silent (SNP) | VAF 44/1206 reads (4%) | called by muse, mutect2
- SPTA1 | c.1794C>T p.I598= | Silent (SNP) | VAF 124/540 reads (23%) | called by muse, mutect2, varscan2
- SULT1A1 | c.36G>A p.L12= | Silent (SNP) | VAF 100/688 reads (15%) | called by muse, mutect2, varscan2
- SYCP2 | c.3645C>T p.N1215= | Silent (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- TRERF1 | c.2949G>A p.V983= | Silent (SNP) | VAF 32/249 reads (13%) | catalogued as rs774288676; called by muse, mutect2, varscan2
- ZNF230 | c.1044C>T p.S348= | Silent (SNP) | VAF 53/270 reads (20%) | catalogued as rs778236001, COSV101431940; called by muse, mutect2, varscan2
- ACTN1 | c.2521-51G>A | Intron (SNP) | VAF 73/255 reads (29%) | called by muse, mutect2, varscan2
- ACTR1A | c.*1196C>G | 3'UTR (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- CTSL3P | n.185G>A | RNA (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- EIF4A2 | c.-12G>A | 5'UTR (SNP) | VAF 15/54 reads (28%) | catalogued as rs370219211; called by muse, mutect2, varscan2
- EP400P1 | n.1588C>G | RNA (SNP) | VAF 20/83 reads (24%) | catalogued as rs558794901; called by muse, mutect2, varscan2
- FBLN2 | c.2155+2046C>T | Intron (SNP) | VAF 107/225 reads (48%) | called by mutect2, varscan2
- FLJ40288 | n.767C>T | RNA (SNP) | VAF 62/274 reads (23%) | catalogued as rs950878118; called by muse, mutect2, varscan2
- RPL28 | c.*3228C>T | 3'UTR (SNP) | VAF 34/135 reads (25%) | catalogued as COSV100689491; called by muse, mutect2, varscan2
- SALL2 | c.-4G>C | 5'UTR (SNP) | VAF 50/389 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.2740A>T | RNA (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
